Gene-level copy-number profile of tumor specimen TCGA-KR-A7K8-01A from TCGA case TCGA-KR-A7K8, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 57.3 years (20,914 days).
Specimen TCGA-KR-A7K8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.c3549d34-542e-4297-8b21-a9e0eca9cd94.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KR-A7K8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/824972b6-476a-48db-af17-f7d65851289c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,517; copy number 2: 34,390; copy number 3: 13,597; copy number 4: 4,244; copy number 5: 1,435; copy number 6: 391; copy number 7: 106; copy number 8: 99; copy number 9: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KR-A7K8-01A-11D-A33B-01): tumor purity 0.5, ploidy 4.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,067 genes in 59 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:99,464,378–101,390,303, 53 genes, copy number 6–7: AL365220.1, LINC01708, PALMD, HMGB3P10, FRRS1, RNU4-75P, Y_RNA, AC096949.1, AGL, AC118553.1, SLC35A3, AC118553.2, RNU6-750P, RNU6-1318P, MFSD14A, AC093019.2, SASS6, AC093019.1, TRMT13, LRRC39, DBT, RPL23AP90, BRI3P1, AL445928.2, AL445928.1, RTCA-AS1, RTCA, MIR553, AC104457.1, AC104457.2, CDC14A, BCAS2P2, AL589990.1, GPR88, AC099670.1, LINC01349, AC099670.3, AC099670.2, VCAM1, EXTL2, AC104506.1, SLC30A7, HNRNPA1P68, DPH5, AC093157.2, AC093157.1, AC093157.3, AC119501.1, AL109741.1, S1PR1, AL109741.2, PPIAP7, LINC01307.
- chr1:153,500,463–155,894,386, 147 genes, copy number 5 (broad region; genes not listed).
- chr1:221,508,559–223,395,465, 36 genes, copy number 5–7: AL360013.2, AL360013.3, AL360013.1, AL360013.4, DUSP10, LINC01655, RNU6-403P, LINC02257, LINC02474, LINC01705, AL356108.1, QRSL1P2, AL513314.1, CICP13, AL513314.2, RNU6-791P, AL592148.2, HHIPL2, TAF1A, TAF1A-AS1, MIA3, AL592148.1, AL592148.3, AIDA, BROX, FAM177B, AL392172.1, DISP1, NDUFB1P2, AL929091.1, TLR5, AL359979.2, AL359979.1, SUSD4, RNU4-57P, CCDC185.
- chr1:227,918,656–229,705,861, 89 genes, copy number 5 (broad region; genes not listed).
- chr1:236,348,257–238,538,305, 34 genes, copy number 5 (within-gene range 3–5): EDARADD, ENO1P1, LGALS8, LGALS8-AS1, AL359921.2, AL359921.1, HEATR1, ACTN2, MTR, RPSAP21, RPL35P1, MT1HL1, AL359259.1, RYR2, RN7SKP195, MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32.
- chr2:201,487,421–202,619,896, 51 genes, copy number 7: C2CD6, MTCO2P16, MTATP6P16, MTCO3P16, MTND3P16, MTND4LP16, MTND4P29, MTND5P31, TMEM237, ENO1P4, AC007279.1, MPP4, RNU6-651P, ALS2, RPS2P16, CDK15, Y_RNA, UBE2V1P11, RNU6-440P, AC069148.1, FZD7, KIAA2012, KIAA2012-AS1, AC079354.2, AC079354.1, PSMA2P3, DAZAP2P1, SUMO1, RPL39P14, NOP58, SNORD70, SNORD70B, SNORD11B, SNORD11, AC064836.3, RN7SL753P, PIMREGP1, AC064836.1, RN7SL40P, AC064836.2, BMPR2, H3P8, RPL13AP12, MTCO1P17, MTCO2P17, MTATP6P17, MTCO3P17, MTND3P17, MTND4LP17, MTND4P30, MTCO1P54.
- chr2:231,362,708–232,351,309, 37 genes, copy number 5: MIR4777, AC017104.1, B3GNT7, ZBTB8OSP2, HIGD2AP1, AC017104.2, NCL, SNORA75, SNORD20, SNORD82, AC017104.3, AC017104.4, RNU2-22P, LINC00471, AC017104.5, NMUR1, RPL21P35, RPL23AP26, AC104634.1, TEX44, RN7SL499P, PTMA, U4, MIR1244-1, PDE6D, AC073476.3, COPS7B, RPL28P2, AC073476.2, AC073476.1, MIR1471, NPPC, DIS3L2, AC019130.1, MIR562, NRBF2P6, ECEL1P3.
- chr3:12,484,432–12,885,211, 16 genes, copy number 8 (within-gene range 4–8): TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022.
- chr3:16,257,061–16,697,479, 14 genes, copy number 6 (within-gene range 3–6): DPH3, OXNAD1, AC090953.1, RFTN1, AC090948.1, AC090948.2, AC090948.3, AC090948.4, AC010727.1, LINC00690, AC010139.1, DAZL, AC091493.1, CDYLP1.
- chr3:42,469,640–44,477,670, 54 genes, copy number 5 (within-gene range 2–5): RPL35AP8, VIPR1, VIPR1-AS1, SEC22C, SS18L2, NKTR, AC006059.1, ZBTB47, AC006059.5, RN7SL567P, KLHL40, HHATL, AC006059.3, HHATL-AS1, CCDC13, AC006059.2, AC006059.4, CCDC13-AS1, LINC02158, HIGD1A, AC099329.1, ACKR2, AC099329.2, AC092042.3, KRBOX1, CYP8B1, HNRNPA1P22, ZNF662, KRBOX1-AS1, GASK1A, AC092042.2, POMGNT2, AC092042.1, AC092042.4, SNRK, RN7SL517P, SNRK-AS1, ANO10, Y_RNA, AC097638.1, ABHD5, AC006055.1, AC006058.2, AC006058.3, RNU6-367P, MIR138-1, AC006058.4, AC006058.1, TOPAZ1, AC104187.1, TCAIM, C3orf86, LINC01988, ZNF445.
- chr3:72,691,705–74,521,140, 27 genes, copy number 5 (within-gene range 2–5): RNA5SP136, AC097369.4, SHQ1, AC134050.1, PSMD12P1, LAPTM4BP2, GXYLT2, Metazoa_SRP, FTH1P23, PPP4R2, RNU7-19P, EBLN2, RNU6-557P, RNU2-64P, CCDC75P1, RNU6-1270P, PDZRN3, RNU7-119P, PDZRN3-AS1, AC117489.1, AC108725.1, LINC02005, Metazoa_SRP, LINC02047, AC016930.1, AKR1B1P2, CNTN3.
- chr3:97,481,177–98,222,966, 21 genes, copy number 5: AC117470.1, AC110491.1, ARL6, AC110491.3, CRYBG3, AC110491.2, RIOX2, AC026100.1, GABRR3, OR5BM1P, OR5AC1, OR5AC2, AC117460.1, OR5AC4P, POU5F1P7, OR5H1, OR5H14, OR5H15, OR5H5P, OR5H3P, OR5H4P.
- chr3:170,908,857–172,831,229, 35 genes, copy number 5 (within-gene range 3–5): AC061708.1, KLF7P1, RNU1-70P, SLC2A2, TNIK, MIR569, Y_RNA, AC092919.1, AC092919.2, RNU6-348P, AC008134.1, PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1.
- chr3:186,439,239–189,325,304, 64 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr4:111,826,881–112,755,917, 30 genes, copy number 5 (within-gene range 2–5): AC004704.1, CCDC34P1, TUBB8P3, AC093663.1, FAM241A, AC093663.2, AC109347.1, AP1AR, AC109347.2, TIFA, ALPK1, RTEL1P1, TOX4P1, NEUROG2, NEUROG2-AS1, RPL23AP94, ZGRF1, H3P14, LARP7, MIR302CHG, MIR367, MIR302D, MIR302A, MIR302C, MIR302B, OSTCP4, AC106864.1, WRBP1, AC017007.3, Y_RNA.
- chr5:175,903,874–177,022,633, 43 genes, copy number 5: AC138965.2, AC138965.1, THOC3, THOC3-AS1, OR1X1P, AC139491.3, AC139491.1, FAM153B, AC139491.7, AC139491.5, AC139491.4, AC139491.6, AC139491.2, AC139491.8, AC139493.2, AC139493.1, SIMC1, BRCC3P1, KIAA1191, AC138956.1, AC138956.2, ARL10, MIR1271, NOP16, HIGD2A, CLTB, AC010297.1, FAF2, RNF44, CDHR2, RN7SL684P, Y_RNA, GPRIN1, SNCB, MIR4281, EIF4E1B, TSPAN17, AC113391.1, AC113391.2, LINC01574, UNC5A, HK3, UIMC1.
- chr6:13,264,861–14,404,289, 25 genes, copy number 5 (within-gene range 3–5): AL008729.1, TBC1D7, AL008729.2, GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1, CD83, AL133259.1, RNU7-133P, AL353152.2, AL353152.1, LINC01108, AL080313.2, AL080313.1.
- chr6:28,732,017–33,200,665, 360 genes, copy number 5 (broad region; genes not listed).
- chr6:41,868,622–45,377,953, 115 genes, copy number 6–8 (broad region; genes not listed).
- chr6:164,928,191–166,389,920, 28 genes, copy number 5 (within-gene range 3–5): AL133538.1, AL136100.1, C6orf118, PDE10A, RNA5SP226, RNU6-730P, AL590302.2, AL590302.1, LINC00602, GAPDHP72, AL627443.3, AL627443.1, AL627443.2, TBXT, LNCDAT, RNU6-153P, AL121956.6, AL121956.1, GNG5P1, AL121956.5, PRR18, AL121956.7, SFT2D1, HNRNPA1P49, AL022069.3, MPC1, AL022069.1, AL022069.2.
- chr7:53,316,149–54,621,131, 19 genes, copy number 5–7: RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P.
- chr7:106,569,876–108,003,213, 29 genes, copy number 5 (within-gene range 3–5): AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1.
- chr7:109,521,981–111,562,517, 13 genes, copy number 6: AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8, AC073114.1, AC073114.2, AC073326.2, IMMP2L, AC073326.1, LRRN3, AC003989.2, AC003989.1.
- chr7:112,206,695–112,896,625, 15 genes, copy number 8 (within-gene range 2–8): ZNF277, RN7SKP187, AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14, AC002463.1, MIPEPP1, TMEM168.
- chr7:113,876,777–115,231,355, 12 genes, copy number 6: PPP1R3A, FOXP2, AC073626.2, AC073626.1, AC003992.1, RNA5SP238, MIR3666, MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA.
- chr7:149,547,154–150,861,504, 48 genes, copy number 5: ZNF767P, KRBA1, ZNF467, SSPOP, ZNF862, AC004877.2, AC004877.1, ATP6V0E2-AS1, ATP6V0E2, AC093458.1, AC093458.2, AC092681.3, AC092681.1, AC092681.2, AC092666.1, AC092666.2, AC006008.1, ACTR3C, ZBED6CL, LRRC61, AC005586.1, RARRES2, REPIN1-AS1, REPIN1, ZNF775, AC073111.2, ZNF775-AS1, AC073111.3, LINC00996, GIMAP8, AC073111.1, STRADBP1, GIMAP7, ALDH7A1P3, GIMAP4, AC069304.3, AC069304.1, GIMAP6, AC069304.2, GIMAP2, GIMAP1, GIMAP1-GIMAP5, GIMAP5, GIMAP3P, BET1P1, TMEM176B, TMEM176A, AOC1.
- chr7:153,715,074–155,966,343, 40 genes, copy number 5: AC005998.1, DPP6, AC005588.1, AC006019.3, AC006019.1, AC006019.2, AC024730.1, AC073336.1, PAXIP1-AS2, PAXIP1, AC093726.1, AC093726.2, PAXIP1-AS1, HTR5A-AS1, HTR5A, AC093726.3, AC092628.2, AC092628.1, RN7SKP280, AC099552.1, AC099552.3, AC099552.5, AC099552.4, AC099552.2, AC144652.1, INSIG1, BLACE, AC008060.1, AC008060.4, AC008060.5, AC008060.3, EN2, CNPY1, AC009403.2, AC008060.2, AC009403.3, AC009403.1, RBM33, SHH, AC021218.1.
- chr8:61,500,556–64,798,737, 45 genes, copy number 5 (within-gene range 2–5): ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8, MIR124-2HG, MIR124-2, AC012535.1, AC090136.1, AC090136.2, AC090136.3, BHLHE22, CYP7B1.
- chr8:70,109,782–71,592,025, 19 genes, copy number 5 (within-gene range 3–5): NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1, EYA1, TRAPPC2P2.
- chr8:79,520,145–80,568,506, 31 genes, copy number 5: AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2.
- chr8:96,068,729–97,149,654, 15 genes, copy number 6: GAPDHP30, AC007992.1, AP003465.2, GDF6, UQCRB, AP003465.1, MTERF3, PTDSS1, Y_RNA, AP003548.1, RNU6-1172P, SDC2, CPQ, AP003117.2, AP003117.1.
- chr8:99,796,615–104,589,024, 122 genes, copy number 6–9 (broad region; genes not listed).
- chr8:121,954,640–122,985,629, 13 genes, copy number 5: AC037486.1, MRPS36P3, SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2.
- chr8:126,325,454–127,482,139, 18 genes, copy number 6: AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2.
- chr8:134,783,694–137,645,564, 19 genes, copy number 5–6 (within-gene range 3–6): AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1.
- chr10:95,711,779–99,659,284, 82 genes, copy number 5–8 (broad region; genes not listed).
- chr11:2,444,684–4,608,231, 94 genes, copy number 5 (broad region; genes not listed).
- chr11:69,737,298–70,436,584, 24 genes, copy number 6: DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr12:24,566,964–25,959,765, 35 genes, copy number 5: LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1.
- chr18:8,609,437–9,889,275, 39 genes, copy number 6 (within-gene range 4–6): RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, AP001531.1, AP005899.2, RPS4XP19, NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1, ANKRD12, Y_RNA, Y_RNA, AP001033.2, AP001033.1, TWSG1, AP001033.3, AP005432.2, RALBP1, AP005432.1, RNU2-27P, PPP4R1, AP001381.1, PPP4R1-AS1, RNU6-903P, LINC02856, KRT18P8, RAB31, AP000902.1, ZNF415P1, RN7SL862P, AC006238.2, RNA5SP449, PIGPP4, TXNDC2.

Autosomal genes at a single copy (total copy number 1): 3,377. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
